Somatic mutation profile of tumor specimen TCGA-D5-6533-01A (aliquot TCGA-D5-6533-01A-11D-1719-10) from TCGA case TCGA-D5-6533, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; Age at diagnosis: 68.4 years (24,971 days).
Specimen TCGA-D5-6533-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8b20bff-2679-4253-ab26-bf107ab56eeb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6533-10A (Blood Derived Normal), aliquot TCGA-D5-6533-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7aafef7-3148-4a3b-9736-85d8e7a59db1

The open-access MAF lists 183 somatic variants for this specimen: 130 protein-altering or splice-affecting, 46 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 46, Nonsense Mutation 11, Frame Shift Del 4, Intron 3, Splice Region 2, RNA 2, In Frame Del 1, Nonstop Mutation 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 88/158 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.4519T>G p.L1507V | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV70026857; called by muse, mutect2, varscan2
- ABTB2 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs903641747, COSV100131510; called by muse, varscan2
- ACAD9 | c.643A>C p.T215P | Missense Mutation (SNP) | VAF 172/353 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV100459377; called by muse, mutect2, varscan2
- ACTL6B | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 150/531 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV50514080; called by muse, mutect2, varscan2
- ALMS1 | c.9866C>T p.P3289L | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs369660958; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMHR2 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs1439647673, COSV99143479; called by muse, mutect2, varscan2
- AP5B1 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs747016732, COSV57502474; called by muse, mutect2, varscan2
- APC | c.2752G>T p.E918* | Nonsense Mutation (SNP) | VAF 67/167 reads (40%) | catalogued as CM040978, COSV57328628, COSV57339762, COSV99965505; called by muse, mutect2, varscan2
- APOBR | c.2491C>T p.R831W (on ENST00000431282; = p.R840W on NM_018690.4) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs769920621, COSV60492358; called by muse, mutect2, varscan2
- ARAP2 | c.1745C>G p.S582C | Missense Mutation (SNP) | VAF 45/282 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as COSV58284294; called by muse, mutect2, varscan2
- ARHGAP36 | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 79/263 reads (30%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs376197707, COSV52265119; called by muse, mutect2, varscan2
- ATM | c.4737A>C p.Q1579H | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.049); catalogued as COSV99591422; called by muse, mutect2, varscan2
- BCHE | c.740G>C p.R247T | Missense Mutation (SNP) | VAF 74/267 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs754253344, COSV52254762; called by muse, mutect2, varscan2
- BMP5 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 222/577 reads (38%) | catalogued as rs550837639, COSV63700675; called by muse, mutect2, varscan2
- CAPN6 | c.1223G>T p.R408L | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60694273, COSV60695421; called by muse, mutect2, varscan2
- CAPRIN2 | c.1924G>C p.D642H | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51831504; called by muse, mutect2, varscan2
- CASS4 | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 155/311 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs775284457, COSV64385690; called by muse, mutect2, varscan2
- CCKBR | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58099739; called by muse, mutect2, varscan2
- CDK5R1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV99912602; called by muse, mutect2, varscan2
- COL4A3 | c.933G>C p.E311D | Missense Mutation (SNP) | VAF 129/484 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.82); catalogued as COSV67414081; called by muse, mutect2, varscan2
- CR2 | c.2644C>A p.Q882K | Missense Mutation (SNP) | VAF 98/232 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0.338); catalogued as COSV100889694; called by muse, mutect2, varscan2
- CRNN | c.1340C>A p.S447* | Nonsense Mutation (SNP) | VAF 57/148 reads (39%) | catalogued as COSV55121266; called by muse, mutect2, varscan2
- CSMD1 | c.3931G>T p.A1311S (on ENST00000520002; = p.A1310S on NM_033225.6) | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs1337036761, COSV100152746; called by muse, mutect2, varscan2
- CYP2A6 | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 52/245 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs143690364, CM141109; called by muse, mutect2, varscan2
- CYP2U1 | c.580A>C p.S194R | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV60548501; called by muse, mutect2, varscan2
- CYP4F12 | c.1541T>C p.L514P | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61172940; called by muse, mutect2, varscan2
- DBN1 | c.1909C>G p.P637A | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1214800698, COSV52788438; called by muse, mutect2, varscan2
- DDX11 | c.1447T>A p.F483I | Missense Mutation (SNP) | VAF 50/640 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV52501493; called by muse, mutect2
- DNAH5 | c.5005G>A p.A1669T | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1294687964, COSV99453100; called by muse, mutect2, varscan2
- DYNC2H1 | c.5050G>T p.G1684* | Nonsense Mutation (SNP) | VAF 35/205 reads (17%) | catalogued as COSV62089636; called by muse, mutect2, varscan2
- ERCC6L | c.2924T>G p.V975G | Missense Mutation (SNP) | VAF 161/546 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100559236; called by muse, mutect2, varscan2
- ESRP1 | c.868A>T p.M290L | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.267); catalogued as COSV64408495; called by muse, mutect2, varscan2
- FANCM | c.1519A>T p.T507S | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as COSV57498613; called by muse, mutect2, varscan2
- FASN | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60751969; called by muse, mutect2, varscan2
- FAT4 | c.7994A>G p.N2665S | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs750389398, COSV100629801; called by muse, mutect2, varscan2
- FBLN1 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.044); catalogued as rs759317468, COSV53044963; called by muse, mutect2, varscan2
- FGD4 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 103/214 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56781608; called by muse, mutect2, varscan2
- FLT4 | c.1930G>A p.A644T | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV56109144; called by muse, mutect2, varscan2
- FMN2 | c.2999C>T p.P1000L | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.722); catalogued as rs772595784, COSV60422524; called by muse, mutect2, varscan2
- FREM2 | c.5626G>A p.V1876I | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs527641289, COSV54832112; called by muse, mutect2, varscan2
- FZD9 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV60669769; called by muse, mutect2, varscan2
- GADL1 | c.579C>A p.Y193* | Nonsense Mutation (SNP) | VAF 24/119 reads (20%) | catalogued as COSV56976616; called by muse, mutect2, varscan2
- GADL1 | c.578A>G p.Y193C | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56976632; called by muse, mutect2, varscan2
- GALNT17 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as COSV61153501; called by muse, mutect2, varscan2
- GLIS3 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs755318788, COSV60925934, COSV60929585; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GML | c.402A>C p.E134D | Missense Mutation (SNP) | VAF 114/288 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.402); catalogued as COSV55276685; called by muse, mutect2, varscan2
- GPR158 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as rs1235084610, COSV66267181; called by muse, mutect2, varscan2
- GRIPAP1 | c.342C>G p.N114K | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV64551378; called by muse, mutect2, varscan2
- GSTP1 | c.-1C>T | Splice Region (SNP) | VAF 7/30 reads (23%) | catalogued as rs45458200; called by muse, mutect2, varscan2
- HADHA | c.40T>A p.S14T | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV58545344; called by muse, varscan2
- HADHA | c.39T>A p.F13L | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV58545349; called by muse, varscan2
- HADHA | c.38T>A p.F13Y | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV58545355; called by muse, varscan2
- HEY1 | c.366T>A p.Y122* | Nonsense Mutation (SNP) | VAF 53/148 reads (36%) | catalogued as COSV61232568; called by muse, mutect2, varscan2
- IFNA5 | c.20T>C p.L7S | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1190436880, COSV52386616; called by muse, mutect2, varscan2
- IGFN1 | c.2933C>A p.P978H (on ENST00000295591 / NM_001367841.1; = p.P3435H on NM_001164586.2) | Missense Mutation (SNP) | VAF 62/103 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55168654; called by muse, mutect2, varscan2
- IL1RAPL1 | c.262C>A p.P88T | Missense Mutation (SNP) | VAF 100/402 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56246505; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1577C>G p.A526G | Missense Mutation (SNP) | VAF 75/583 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV100149635; called by muse, mutect2, varscan2
- IQCE | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 74/145 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs367731945; called by muse, mutect2, varscan2
- KCNJ6 | c.1049A>G p.D350G | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55711109; called by muse, mutect2, varscan2
- KCNJ8 | c.347A>T p.E116V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53715571; called by muse, mutect2, varscan2
- KLHL34 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.297); catalogued as COSV65278967; called by muse, mutect2, varscan2
- KLHL4 | c.1316C>A p.A439D | Missense Mutation (SNP) | VAF 54/858 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.673); catalogued as COSV100910098; called by muse, mutect2
- MGAT5B | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as rs773776997, COSV100048798; called by muse, mutect2, varscan2
- MID1 | c.668T>C p.L223S | Missense Mutation (SNP) | VAF 33/318 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV58192700; called by muse, mutect2, varscan2
- MPDZ | c.559C>G p.Q187E | Missense Mutation (SNP) | VAF 190/426 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs768024665, COSV59936865; called by muse, mutect2, varscan2
- MUC4 | c.15507A>T p.L5169= (on ENST00000463781 / NM_018406.7; = p.L933= on NM_004532.6) | Splice Region (SNP) | VAF 33/167 reads (20%) | catalogued as COSV57772772; called by muse, mutect2, varscan2
- MXRA5 | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 183/655 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs768203807, COSV54222166; called by muse, mutect2, varscan2
- MYO10 | c.2780T>A p.L927H | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as COSV99946073; called by muse, mutect2, varscan2
- MYO5C | c.1237A>G p.I413V | Missense Mutation (SNP) | VAF 74/113 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.26); catalogued as COSV55904019; called by muse, mutect2, varscan2
- NKAPL | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs1306384118, COSV59199239; called by muse, mutect2, varscan2
- NR0B1 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs1177939128, CD105942, COSV66763760; called by muse, mutect2, varscan2
- NUP210L | c.2375G>C p.R792T | Missense Mutation (SNP) | VAF 119/309 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV55144229; called by muse, mutect2, varscan2
- OBSCN | c.17288C>T p.T5763M | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201372419; called by muse, mutect2, varscan2
- OGDHL | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370905720; called by muse, mutect2, varscan2
- OR10A3 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs1172430951, COSV62459299; called by muse, mutect2, varscan2
- OR10J1 | c.363C>G p.D121E | Missense Mutation (SNP) | VAF 92/255 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV71128477; called by muse, mutect2, varscan2
- OR1A1 | c.44T>A p.L15Q | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58403393; called by muse, mutect2, varscan2
- OR2M5 | c.7T>A p.W3R | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV63545936; called by muse, mutect2, varscan2
- PBRM1 | c.2506C>T p.R836W | Missense Mutation (SNP) | VAF 63/238 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1438592568, COSV56266126; called by muse, mutect2, varscan2
- PCDHB8 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 64/468 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); catalogued as rs1483942587, COSV50753538; called by muse, varscan2
- PCDHGA5 | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.185); catalogued as rs555568322, COSV53917387; called by muse, mutect2, varscan2
- PCDHGB1 | c.1195_1197del p.K399del | In Frame Del (DEL) | VAF 34/105 reads (32%) | catalogued as COSV53917373; called by mutect2, pindel, varscan2
- PIK3CG | c.3308A>C p.*1103Sext*10 | Nonstop Mutation (SNP) | VAF 36/240 reads (15%) | catalogued as COSV63246830; called by muse, mutect2, varscan2
- PKD1 | c.7649G>A p.G2550D | Missense Mutation (SNP) | VAF 168/394 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV99238873; called by muse, mutect2, varscan2
- PKD1L1 | c.898G>A p.V300M | Missense Mutation (SNP) | VAF 136/272 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1445381943, COSV56961009; called by muse, mutect2, varscan2
- PLAAT5 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.978); catalogued as rs1456267904, COSV57136545; called by mutect2, varscan2
- PLSCR5 | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs373289584; called by muse, mutect2, varscan2
- PLXNA4 | c.2729C>A p.P910H | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); catalogued as COSV58113551; called by muse, mutect2, varscan2
- PPP4R2 | c.636C>A p.H212Q | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV55594627; called by muse, mutect2, varscan2
- PRKD1 | c.1596G>A p.W532* | Nonsense Mutation (SNP) | VAF 103/195 reads (53%) | catalogued as COSV59562408; called by muse, mutect2, varscan2
- PTGER4 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.244); catalogued as COSV100201586, COSV56720357; called by muse, mutect2, varscan2
- RB1 | c.2579A>G p.K860R | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99926278; called by muse, mutect2, varscan2
- RHAG | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57703594; called by muse, mutect2, varscan2
- RIPOR3 | c.2148G>C p.K716N | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50386600; called by muse, mutect2, varscan2
- RPS6KC1 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 132/693 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100874051; called by muse, mutect2, varscan2
- SACS | c.11261A>T p.N3754I | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV66536791; called by muse, mutect2, varscan2
- SFTPD | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as rs775188444, COSV64852769; called by muse, mutect2, varscan2
- SGO2 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 26/698 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100764777; called by muse, mutect2
- SHC1 | c.1482C>G p.S494R (on ENST00000368445 / NM_183001.5; = p.S385R on NM_003029.5) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100821145; called by muse, mutect2, varscan2
- SLC5A7 | c.502T>C p.S168P | Missense Mutation (SNP) | VAF 235/729 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50889917; called by muse, mutect2, varscan2
- SLC6A19 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 109/296 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs1344159365, COSV100443706; called by muse, mutect2, varscan2
- SLIT2 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.56); catalogued as rs1225312424, COSV56565513; called by muse, mutect2, varscan2
- SMC2 | c.779T>A p.V260D | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV53956265; called by muse, mutect2, varscan2
- SRPK3 | c.1165A>T p.N389Y | Missense Mutation (SNP) | VAF 67/234 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV54206648; called by muse, mutect2, varscan2
- TEX47 | c.24G>C p.Q8H | Missense Mutation (SNP) | VAF 115/697 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV51878470, COSV51879802; called by muse, mutect2, varscan2
- THSD1 | c.2187C>A p.Y729* | Nonsense Mutation (SNP) | VAF 39/218 reads (18%) | catalogued as COSV99319039; called by muse, mutect2, varscan2
- TMEM155 | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 24/382 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.66); catalogued as COSV100530081; called by muse, mutect2
- TMTC3 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 140/295 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.234); catalogued as COSV57122831; called by muse, mutect2, varscan2
- TRPC3 | c.398A>C p.E133A (on ENST00000379645 / NM_001366479.2; = p.E60A on NM_003305.2) | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV53373254; called by muse, mutect2, varscan2
- TSHZ3 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1430882038, COSV53667107; called by muse, mutect2, varscan2
- TTN | c.28769A>T p.E9590V (on ENST00000591111; = p.E8663V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/134 reads (33%) | PolyPhen benign (0.173); catalogued as COSV59949044; called by muse, mutect2, varscan2
- UBA7 | c.2846G>A p.G949D | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.163); catalogued as COSV100323734; called by muse, mutect2, varscan2
- UBQLNL | c.802A>T p.N268Y | Missense Mutation (SNP) | VAF 58/285 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV66492890; called by muse, mutect2, varscan2
- USP28 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 43/105 reads (41%) | catalogued as COSV50157369; called by muse, mutect2, varscan2
- USP4 | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 130/263 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55535671; called by muse, mutect2, varscan2
- VEPH1 | c.2156T>C p.I719T | Missense Mutation (SNP) | VAF 135/280 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV62877225; called by muse, mutect2, varscan2
- XG | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 132/478 reads (28%) | catalogued as rs1320169079, COSV66985451; called by muse, mutect2, varscan2
- XIRP2 | c.118G>A p.E40K (on ENST00000628543; = p.E215K on NM_152381.6) | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as rs1449740160, COSV54681396, COSV54689028; called by muse, mutect2, varscan2
- XKR6 | c.595C>A p.L199I | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.936); catalogued as COSV52007964; called by muse, mutect2, varscan2
- ZNF43 | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.48); catalogued as rs760588871, COSV61683312; called by muse, mutect2, varscan2
- ZNF442 | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1277351938, COSV54420935; called by muse, mutect2, varscan2
- ZNF608 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 116/274 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100102304; called by muse, mutect2, varscan2
- ZSCAN31 | c.206G>T p.R69M | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.69); catalogued as COSV60180485; called by muse, mutect2, varscan2
- APC | c.4465_4481del p.L1489Kfs*19 | Frame Shift Del (DEL) | VAF 41/135 reads (30%) | called by mutect2, pindel, varscan2
- DPP6 | c.1711_1714+1del | Frame Shift Del (DEL) | VAF 105/375 reads (28%) | called by mutect2, pindel, varscan2
- DYNC2LI1 | c.688del p.I230Yfs*38 | Frame Shift Del (DEL) | VAF 73/292 reads (25%) | called by mutect2, pindel, varscan2
- PRAMEF14 | c.47G>T p.S16I | Missense Mutation (SNP) | VAF 104/168 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SREK1 | c.1103dup p.Y368* | Nonsense Mutation (INS) | VAF 180/672 reads (27%) | called by pindel, varscan2
- TRAP1 | c.233_234del p.T78Rfs*11 | Frame Shift Del (DEL) | VAF 64/206 reads (31%) | called by pindel, varscan2
- ADAMTS12 | c.1983C>T p.G661= | Silent (SNP) | VAF 51/128 reads (40%) | catalogued as rs776324042, COSV100710517, COSV61254656; called by muse, mutect2, varscan2
- AZIN2 | c.178C>T p.L60= | Silent (SNP) | VAF 56/87 reads (64%) | catalogued as COSV53856524; called by muse, mutect2, varscan2
- BCORL1 | c.2607T>C p.F869= | Silent (SNP) | VAF 49/372 reads (13%) | catalogued as COSV99500609; called by muse, mutect2, varscan2
- BOD1L1 | c.8472C>T p.T2824= | Silent (SNP) | VAF 83/522 reads (16%) | catalogued as rs1015247352, COSV50008362; called by muse, mutect2, varscan2
- CDH22 | c.579G>A p.S193= | Silent (SNP) | VAF 313/645 reads (49%) | catalogued as rs369777279; called by muse, mutect2, varscan2
- CFP | c.276G>A p.T92= | Silent (SNP) | VAF 42/504 reads (8%) | catalogued as rs749722640, COSV55949944; called by muse, mutect2
- CHDH | c.285G>T p.V95= | Silent (SNP) | VAF 31/55 reads (56%) | catalogued as COSV59456520; called by muse, mutect2, varscan2
- CHRDL1 | c.927C>T p.D309= (on ENST00000372045; = p.D315= on NM_145234.4) | Silent (SNP) | VAF 139/507 reads (27%) | catalogued as rs377115708, COSV54325382; called by muse, mutect2, varscan2
- CLBA1 | c.543T>A p.P181= | Silent (SNP) | VAF 62/91 reads (68%) | catalogued as COSV66347898; called by muse, mutect2, varscan2
- CMYA5 | c.8160T>G p.T2720= | Silent (SNP) | VAF 27/184 reads (15%) | catalogued as COSV71404651; called by muse, mutect2, varscan2
- CNR1 | c.90C>T p.Y30= | Silent (SNP) | VAF 84/230 reads (37%) | catalogued as rs774890934, COSV62988126; called by muse, mutect2, varscan2
- CPVL | c.138C>G p.T46= | Silent (SNP) | VAF 82/298 reads (28%) | catalogued as COSV55300523; called by muse, mutect2, varscan2
- DAGLB | c.39C>T p.I13= | Silent (SNP) | VAF 37/215 reads (17%) | catalogued as COSV51703030; called by muse, mutect2, varscan2
- DNAH7 | c.4170C>A p.L1390= | Silent (SNP) | VAF 74/407 reads (18%) | catalogued as COSV56756781; called by muse, mutect2, varscan2
- ESRRB | c.117C>T p.S39= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as rs1207603998, COSV99834964; called by muse, mutect2, varscan2
- FAT4 | c.996C>T p.S332= | Silent (SNP) | VAF 102/177 reads (58%) | catalogued as COSV67883576; called by muse, mutect2, varscan2
- FLI1 | c.996C>T p.Y332= | Silent (SNP) | VAF 40/152 reads (26%) | catalogued as rs752016751, COSV55643083; ClinVar: likely benign; called by muse, mutect2, varscan2
- GIMAP7 | c.646C>A p.R216= | Silent (SNP) | VAF 25/137 reads (18%) | catalogued as COSV57958744, COSV57960327; called by muse, mutect2, varscan2
- HECW1 | c.1749C>T p.D583= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs763171223, COSV67825593, COSV67840682; called by muse, mutect2, varscan2
- HTR3A | c.714C>T p.I238= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs764823131, COSV55468594; called by muse, mutect2, varscan2
- IL13RA2 | c.9C>T p.F3= | Silent (SNP) | VAF 91/567 reads (16%) | catalogued as COSV54564006; called by muse, mutect2, varscan2
- INF2 | c.441G>A p.L147= | Silent (SNP) | VAF 74/112 reads (66%) | catalogued as COSV53031063; called by muse, mutect2, varscan2
- KCND1 | c.93G>C p.P31= | Silent (SNP) | VAF 51/168 reads (30%) | catalogued as rs368004864, COSV54415720, COSV99501798, COSV99502109; called by muse, mutect2, varscan2
- MTM1 | c.990T>C p.P330= | Silent (SNP) | VAF 102/873 reads (12%) | catalogued as rs1557414127, COSV60334212; called by muse, mutect2, varscan2
- NACC2 | c.393G>A p.Q131= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs1337184599; called by muse, mutect2, varscan2
- NEUROD6 | c.456C>T p.I152= | Silent (SNP) | VAF 54/193 reads (28%) | catalogued as rs533417088, COSV51771941; called by muse, mutect2, varscan2
- NLGN2 | c.192C>A p.G64= | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, varscan2
- OR14J1 | c.858C>A p.V286= | Silent (SNP) | VAF 48/117 reads (41%) | catalogued as COSV65845575; called by muse, mutect2, varscan2
- P2RY8 | c.312C>T p.Y104= | Silent (SNP) | VAF 173/711 reads (24%) | catalogued as rs1425189992, COSV67176956; called by muse, mutect2, varscan2
- PCDHA10 | c.792C>T p.N264= | Silent (SNP) | VAF 95/260 reads (37%) | catalogued as rs782759448, COSV56485927; called by muse, mutect2, varscan2
- RAB5C | c.300C>G p.V100= | Silent (SNP) | VAF 21/142 reads (15%) | catalogued as COSV60524438; called by muse, mutect2, varscan2
- RYR1 | c.5463C>T p.D1821= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs753150627, COSV62091944; called by muse, mutect2, varscan2
- RYR2 | c.3444C>A p.G1148= | Silent (SNP) | VAF 73/213 reads (34%) | catalogued as COSV63672238; called by muse, mutect2, varscan2
- SHC3 | c.1224G>A p.T408= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs369413725; called by muse, mutect2, varscan2
- SREK1 | c.888T>C p.G296= | Silent (SNP) | VAF 93/234 reads (40%) | catalogued as COSV52332123, COSV52333152; called by muse, mutect2, varscan2
- ST3GAL3 | c.942C>T p.I314= (on ENST00000361392 / NM_174964.4; = p.I299= on NM_006279.5) | Silent (SNP) | VAF 76/109 reads (70%) | catalogued as rs766347682, COSV53512331; called by muse, mutect2, varscan2
- SYNE1 | c.3888C>A p.I1296= (on ENST00000367255 / NM_182961.4; = p.I1303= on NM_033071.3) | Silent (SNP) | VAF 124/294 reads (42%) | catalogued as COSV54921622, COSV54956917; called by muse, mutect2, varscan2
- TLN1 | c.2727C>T p.I909= | Silent (SNP) | VAF 30/226 reads (13%) | catalogued as COSV59205716; called by muse, mutect2, varscan2
- TNXB | c.4842G>A p.P1614= (on ENST00000647633; = p.P1367= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as rs560963735, COSV100925946; called by muse, mutect2, varscan2
- TPMT | c.520C>T p.L174= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV59428470; called by muse, mutect2, varscan2
- TRIM9 | c.702G>A p.L234= | Silent (SNP) | VAF 67/106 reads (63%) | catalogued as COSV53614469; called by muse, mutect2, varscan2
- TTN | c.5742G>A p.A1914= (on ENST00000591111; = p.A1868= on NM_003319.4) | Silent (SNP) | VAF 148/481 reads (31%) | catalogued as rs368719553; ClinVar: likely benign; called by muse, mutect2, varscan2
- UGGT1 | c.2973T>G p.A991= | Silent (SNP) | VAF 18/162 reads (11%) | called by muse, mutect2, varscan2
- ZFR | c.2970T>C p.P990= | Silent (SNP) | VAF 71/177 reads (40%) | catalogued as COSV54051515; called by muse, mutect2, varscan2
- ZNF449 | c.759G>A p.E253= | Silent (SNP) | VAF 176/726 reads (24%) | catalogued as COSV100203048; called by muse, mutect2, varscan2
- ZNF648 | c.24C>T p.D8= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV60570142; called by muse, mutect2, varscan2
- AC244258.1 | n.998G>T | RNA (SNP) | VAF 47/123 reads (38%) | called by muse, mutect2, varscan2
- AL162726.3 | n.255+83283G>A | Intron (SNP) | VAF 50/161 reads (31%) | called by muse, mutect2, varscan2
- CEACAM16 | chr19:44699251 G>A | 5'Flank (SNP) | VAF 91/404 reads (23%) | catalogued as rs375005046, COSV69186924; called by muse, mutect2, varscan2
- FCN2 | c.*2C>T | 3'UTR (SNP) | VAF 17/52 reads (33%) | catalogued as COSV99391419; called by muse, mutect2, varscan2
- HERC2P3 | n.2011C>T | RNA (SNP) | VAF 121/272 reads (44%) | catalogued as rs1160677325; called by muse, mutect2, varscan2
- KCNIP4 | c.62-421103T>C | Intron (SNP) | VAF 38/115 reads (33%) | catalogued as COSV66165697; called by muse, mutect2, varscan2
- PCDHA3 | c.2394+26C>A | Intron (SNP) | VAF 20/117 reads (17%) | catalogued as COSV63539870; called by muse, mutect2, varscan2
